Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5696, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5696-01A (Primary Tumor).

PATIENT HISTORY:
PRE-OP DIAGNOSIS: Renal carcinoma.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Right nephrectomy.

FINAL DIAGNOSIS:

PART 1:

KIDNEY, RIGHT, PARTIAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE.
- B. FUHRMAN NUCLEAR GRADE IS 4 OF 4.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 10.6 cm.
- D. THE CARCINOMA FOCALLY INVADES INTO THE RENAL SINUS FAT.
- E. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- F. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- H. THE NON-NEOPLASTIC KIDNEY SHOWS CHANGES RELATED TO PROXIMITY TO THE TUMOR AND MILD CHRONIC VASCULAR CHANGES, APPROPRIATE FOR AGE.
- I. TNM STAGE: pT3a NX MX.

PART 2:

ADRENAL GLAND, CLINICALLY LABELED RIGHT-
ADRENAL GLAND WITH NO SPECIFIC PATHOLOGIC CHANGE.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE:	Radical nephrectomy
LATERALITY:	Right
TUMOR SITE:	Upper pole
FOCALITY:	Unifocal
TUMOR SIZE:	Greatest dimension: 10.6 cm Additional dimensions: 7.5x6.7 cm
MACROSCOPIC EXTENT OF TUMOR:	Tumor extension into perinephric tissues
HISTOLOGIC TYPE:	Clear cell (conventional) renal carcinoma
HISTOLOGIC GRADE (Fuhrman Nuclear Grade):	G4
PATHOLOGIC STAGING (pTNM):	pT3a pNX Number of regional lymph nodes examined: 0 Number of regional lymph nodes involved: 0 pMX
MARGINS:	Margins uninvolved by invasive carcinoma
ADRENAL GLAND:	Uninvolved by tumor
VENOUS (LARGE VESSEL) INVASION (V):	Absent
LYMPHATIC (SMALL VESSEL) INVASION (L):	Absent
ADDITIONAL PATHOLOGIC FINDINGS:	None identified

Source: NCI Genomic Data Commons file 20c11f5a-d47c-4191-a2f4-05e98875eae0 (TCGA-B0-5696.6BB0E08F-3C19-4F73-8C01-6FD1F063F4F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).